Gene-level copy-number profile of tumor specimen TCGA-CR-7364-01A from TCGA case TCGA-CR-7364, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.2 years (24,192 days).
Specimen TCGA-CR-7364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.11a18cf3-0980-40f1-8738-eb4e933463e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7364-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfd28869-92f2-4e66-8781-003aa6acc8bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 14,048; copy number 2: 41,046; copy number 3: 4,411; copy number 6: 90; copy number 7: 19; copy number 10: 53; copy number 15: 62; copy number 21: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7364-01A-11D-2010-01): tumor purity 0.54, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,957,394–22,214,672, 67 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 248 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–50,846,519, 5 genes, copy number 7 (within-gene range 1–7): EMB, AC112187.2, AC112187.1, AC112187.3, PARP8.
- chr5:72,087,782–72,916,733, 19 genes, copy number 6 (within-gene range 1–6): AC025774.1, MAP1B, MIR4803, MRPS27, RN7SL153P, PTCD2, AC093278.1, YBX1P5, AC093278.2, ZNF366, LINC02056, AC063979.1, RPL7P22, H2BL1P, Y_RNA, AC035140.1, TNPO1, MIR4804, RPL35AP13.
- chr7:54,185,071–54,257,577, 1 gene, copy number 21 (within-gene range 1–21): AC092848.2.
- chr7:54,330,670–62,275,678, 156 genes, copy number 6–21 (broad region; genes not listed).
- chr8:37,843,268–40,172,612, 67 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
